Gene-level copy-number profile of tumor specimen TCGA-AN-A0FS-01A from TCGA case TCGA-AN-A0FS, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 55.7 years (20,352 days).
Specimen TCGA-AN-A0FS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.5ed36cde-08a1-439e-8b03-7ed3fbddbacf.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AN-A0FS-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/dacd59de-588e-49be-b0a2-a2e4550f0d57

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 4,210; copy number 2: 52,510; copy number 3: 153; copy number 4: 1,350; copy number 5: 1,310; copy number 6: 47; copy number 8: 6; copy number 9: 120; copy number 10: 74; copy number 13: 35.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AN-A0FS-01A-11D-A036-01): tumor purity 0.64, ploidy 2.04, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,592 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:188,013,642–248,919,946, 1,254 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr11:54,591,480–55,344,231, 20 genes, copy number 10: OR4C50P, OR4C46, OR4C7P, OR4R2P, OR4A4P, OR4A3P, OR4A2P, OR4A8, OR4A7P, OR4A5, OR4A6P, TRIM48, AP005597.4, AP005597.3, AP005597.2, TRIM51HP, AP005597.1, OR4A11P, OR4A12P, OR4A16.
- chr11:56,750,330–59,713,845, 138 genes, copy number 6–13 (broad region; genes not listed).
- chr11:59,728,519–59,754,975, 4 genes, copy number 6: OR10Y1P, OR10V3P, OR10V2P, AP000640.1.
- chr11:59,852,800–60,071,115, 9 genes, copy number 5 (within-gene range 1–5): TCN1, OOSP3, SRD5A3P1, OOSP1, AP000790.1, OOSP4A, OOSP4B, OOSP2, MS4A3.
- chr11:69,467,598–74,311,640, 167 genes, copy number 5–9 (within-gene range 2–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,210. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
